Surgical pathology report (de-identified scan), TCGA case TCGA-RR-A6KB, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital AZ, specimen TCGA-RR-A6KB-01A (Primary Tumor).

Pathology Report

Date of Surgery:

Diagnosis:

Right frontal glioblastoma

Discussion:

In the area of cellular tumor, less than 10% of the cells are immunoreactive for MGMT. Many of these are recognizable as endothelial cells. The neoplastic cells are negative for MGMT expression.

Microscopic Description:

Sections demonstrate gray and white matter with cellular and diffusely infiltrating astrocytoma. Tumor cells demonstrate generally moderate cytologic atypia. In multicellular areas, numerous scattered mitotic figures are seen. These areas also demonstrate microvascular proliferation and necrosis with the latter sometimes demonstrating pseudopalisading.

hw 6/25/13

Source: NCI Genomic Data Commons file b2e5cf3e-b501-4068-bd6c-06f3ddd62240 (TCGA-RR-A6KB.FE890D7D-5BB3-4A91-804E-894CA44AA71B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).